Gene-level copy-number profile of tumor specimen ALCH-B4XN-TTP1-A from ALCHEMIST case ALCH-B4XN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.4 years (24,992 days).
Specimen ALCH-B4XN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b907e865-9770-4b13-ae41-979160bd2473.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4XN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/5b6b64ec-9d7a-4eee-9fb0-94825cf99c43

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 13,472; copy number 2: 33,607; copy number 3: 7,273; copy number 4: 2,739; copy number 5: 247; copy number 6: 630; copy number 7: 189; copy number 8: 125; copy number 9: 44; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:960,584–1,000,172, 5 genes: KLHL17, PLEKHN1, PERM1, AL645608.7, HES4.
- chr1:1,020,120–1,074,306, 5 genes: AGRN, AL645608.5, AL390719.1, AL645608.8, RNF223.
- chr1:1,203,508–1,232,067, 3 genes: TNFRSF18, TNFRSF4, SDF4.
- chr1:1,324,756–1,349,418, 4 genes: CPTP, TAS1R3, DVL1, MIR6808.
- chr16:981,770–1,510,457, 45 genes (within-gene range 0–3): SOX8, AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1, AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10, TPSB2, TPSAB1, TPSD1, AC120498.2, PRSS29P, AC120498.7, AC120498.5, TPSP2, AC120498.4, AC120498.9, UBE2I, AL031714.1, RPS20P2, BAIAP3, TSR3, GNPTG, AL031709.1, UNKL, AL032819.1, C16orf91, PERCC1, CCDC154, AL032819.2, CLCN7, AL031600.3, AL031600.1, AL031600.2, RPS3AP2, PTX4, TELO2.
- chr16:1,512,979–1,555,580, 3 genes (within-gene range 0–3): AL031705.1, TMEM204, AL031719.1.
- chr16:1,751,559–1,752,262, 1 gene (within-gene range 0–3): AL031717.1.
- chr21:36,016,079–36,016,546, 1 gene: RPL23AP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,238 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–20,937,800, 350 genes, copy number 5–7 (broad region; genes not listed).
- chr5:26,382,519–45,895,970, 277 genes, copy number 6–7 (broad region; genes not listed).
- chr8:79,891,553–81,924,348, 60 genes, copy number 5–9: AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235.
- chr8:82,098,451–82,292,379, 2 genes, copy number 5: LINC02839, HNRNPA1P4.
- chr8:112,222,928–113,436,939, 2 genes, copy number 8 (within-gene range 3–8): CSMD3, AC024996.1.
- chr8:113,376,669–120,542,133, 61 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:126,072,587–130,655,712, 60 genes, copy number 5: KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1.
- chr9:67,512,034–67,515,393, 1 gene, copy number 8: BX664730.1.
- chr14:20,138,820–20,936,255, 58 genes, copy number 5: OR4N5, PSMB7P1, GTF2IP22, OR11G1P, OR11G2, OR11H5P, OR11H6, OR11H7, OR11H4, TTC5, AL356019.2, AL356019.1, CCNB1IP1, AL355075.6, SNORA79B, SNORD126, AL355075.4, RPPH1, PARP2, AL355075.1, TEP1, RNA5SP382, KLHL33, AL355075.5, OSGEP, AL355075.2, APEX1, PIP4P1, PNP, AL355075.3, RNASE10, PTCD2P1, SETP1, RNASE9, AL163195.3, RNASE11, AL163195.2, RNASE12, AL163195.1, OR6S1, Y_RNA, ANG, RNASE4, AL163636.1, EGILA, RANBP20P, EDDM3DP, EDDM3A, EDDM3B, RNASE6, AL133371.2, RNASE1, AL133371.3, AL133371.1, RNASE3, AL355922.4, AL355922.3, AL355922.1.
- chr14:26,443,090–27,295,516, 9 genes, copy number 6 (within-gene range 4–6): NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307.
- chr14:29,576,479–30,191,898, 1 gene, copy number 6 (within-gene range 4–6): PRKD1.
- chr14:29,811,916–40,390,547, 181 genes, copy number 6–9 (broad region; genes not listed).
- chr14:42,989,201–47,675,605, 45 genes, copy number 6–8 (within-gene range 4–8): AL163153.1, TUBBP3, HNRNPUP1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L, MDGA2, AL359951.1, RPA2P1, RPL13AP2, RPS15AP3.
- chr14:58,646,631–64,338,112, 94 genes, copy number 6–11 (within-gene range 2–11) (broad region; genes not listed).
- chr16:65,141,751–66,873,256, 34 genes, copy number 5 (within-gene range 2–5): LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1, AC022164.1, AC025281.1, RNA5SP428, CDH5, LINC00920, BEAN1, AC132186.1, BEAN1-AS1, AC010542.3, TK2, AC010542.2, AC010542.4, Y_RNA, CKLF, CKLF-CMTM1, AC010542.5, CMTM1, CMTM2, AC010542.1, CMTM3, CMTM4, DYNC1LI2, AC018557.1, AC018557.3, AC018557.2, AC044802.1, TERB1, NAE1.
- chr16:68,591,382–68,630,968, 3 genes, copy number 5: AC126773.6, AC126773.1, AC126773.2.

Autosomal genes at a single copy (total copy number 1): 13,472. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
